Somatic mutation profile of tumor specimen ALCH-B4G7-TTP1-A (aliquot ALCH-B4G7-TTP1-A-1-0-D-A799-36) from ALCHEMIST case ALCH-B4G7, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 71.6 years (26,135 days).
Specimen ALCH-B4G7-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) afb36726-63cd-4d86-b321-3219a47de18a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B4G7-NB1-A (Blood Derived Normal), aliquot ALCH-B4G7-NB1-A-1-0-D-A799-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/958dd3c7-4d87-4c3c-8898-16d1cce3487f

The open-access MAF lists 42 somatic variants for this specimen: 30 protein-altering or splice-affecting, 8 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 8, Nonsense Mutation 2, 3'UTR 2, Intron 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS13 | c.446C>T p.S149L | Missense Mutation (SNP) | VAF 61/482 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.624); catalogued as rs377681196, COSV63022259; called by muse, mutect2, varscan2
- EPRS1 | c.394G>A p.A132T | Missense Mutation (SNP) | VAF 84/756 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0.015); catalogued as rs1277708879; called by muse, mutect2, varscan2
- EXT1 | c.1263G>T p.K421N | Missense Mutation (SNP) | VAF 17/487 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as COSV65481132; called by muse, mutect2
- FAM171A1 | c.220G>A p.A74T | Missense Mutation (SNP) | VAF 20/347 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.442); catalogued as rs762827738, COSV65317711; called by muse, mutect2
- RC3H2 | c.1525C>T p.R509C | Missense Mutation (SNP) | VAF 34/282 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as rs773008821, COSV100605569; called by muse, mutect2, varscan2
- RELN | c.5594C>T p.S1865L | Missense Mutation (SNP) | VAF 16/362 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.831); catalogued as rs1386230430; called by muse, mutect2
- TTN | c.36823G>T p.E12275* (on ENST00000591111; = p.E4851* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 36/526 reads (7%) | catalogued as COSV60274432; called by muse, mutect2
- ACAN | c.4943A>T p.D1648V | Missense Mutation (SNP) | VAF 16/448 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2
- ALK | c.2689C>T p.Q897* | Nonsense Mutation (SNP) | VAF 30/239 reads (13%) | called by muse, mutect2, varscan2
- AP1M2 | c.325A>T p.I109F | Missense Mutation (SNP) | VAF 8/208 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); called by muse, mutect2
- ATXN7L1 | c.874G>C p.D292H | Missense Mutation (SNP) | VAF 13/341 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- CDC14A | c.1598A>T p.N533I | Missense Mutation (SNP) | VAF 16/306 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.621); called by muse, mutect2
- CLSTN2 | c.611A>T p.D204V | Missense Mutation (SNP) | VAF 18/240 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); called by muse, mutect2
- FBXO31 | c.910C>G p.L304V | Missense Mutation (SNP) | VAF 9/166 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.534); called by muse, mutect2
- GRAMD2A | c.332G>T p.W111L | Missense Mutation (SNP) | VAF 12/191 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2
- IFNGR1 | c.219G>T p.W73C | Missense Mutation (SNP) | VAF 14/180 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MRPS9 | c.649G>C p.D217H | Missense Mutation (SNP) | VAF 9/190 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); called by muse, mutect2
- NLRP4 | c.1098G>T p.Q366H | Missense Mutation (SNP) | VAF 18/247 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.753); called by muse, mutect2
- PCDHGB5 | c.761A>T p.N254I | Missense Mutation (SNP) | VAF 19/249 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); called by muse, mutect2
- PDLIM5 | c.1286G>A p.G429E | Missense Mutation (SNP) | VAF 6/127 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PLG | c.2239G>A p.G747R | Missense Mutation (SNP) | VAF 25/464 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RBM10 | c.2668-2A>C p.X890_splice | Splice Site (SNP) | VAF 16/68 reads (24%) | called by muse, mutect2, varscan2
- RMDN2 | c.176A>T p.H59L | Missense Mutation (SNP) | VAF 32/297 reads (11%) | SIFT tolerated (0.47); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- SEC23B | c.634C>T p.P212S | Missense Mutation (SNP) | VAF 28/844 reads (3%) | SIFT tolerated (0.19); PolyPhen benign (0.009); called by muse, mutect2
- SLC25A40 | c.427A>T p.I143L | Missense Mutation (SNP) | VAF 34/258 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.223); called by muse, varscan2
- VPS13B | c.6277G>T p.D2093Y | Missense Mutation (SNP) | VAF 20/575 reads (3%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.467); called by muse, mutect2
- WWTR1 | c.256C>T p.R86C | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- YIPF1 | c.308C>T p.P103L | Missense Mutation (SNP) | VAF 15/408 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF804A | c.3416C>A p.T1139N | Missense Mutation (SNP) | VAF 9/116 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.08); called by muse, mutect2
- ZSCAN10 | c.2049T>G p.N683K (on ENST00000252463; = p.N738K on NM_032805.3) | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.561); called by muse, mutect2, varscan2
- CNGA4 | c.402G>A p.P134= | Silent (SNP) | VAF 16/157 reads (10%) | catalogued as rs928509559; called by muse, mutect2
- CSPG4 | c.612G>A p.L204= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as rs774009871; called by muse, mutect2, varscan2
- CTBS | c.789G>T p.L263= | Silent (SNP) | VAF 12/221 reads (5%) | called by muse, mutect2
- FANCM | c.3138A>G p.Q1046= | Silent (SNP) | VAF 19/408 reads (5%) | called by muse, mutect2
- IL9 | c.36C>T p.L12= | Silent (SNP) | VAF 16/485 reads (3%) | catalogued as COSV50853503; called by muse, mutect2
- PSMA1 | c.189T>C p.I63= | Silent (SNP) | VAF 14/208 reads (7%) | called by muse, mutect2
- PTCHD4 | c.1299G>A p.T433= | Silent (SNP) | VAF 26/270 reads (10%) | catalogued as rs771084561, COSV59781838; called by muse, mutect2
- SCN5A | c.1128C>G p.R376= | Silent (SNP) | VAF 8/220 reads (4%) | called by muse, mutect2
- FBLN5 | c.*5C>G | 3'UTR (SNP) | VAF 16/386 reads (4%) | called by muse, mutect2
- GUCA1B | c.*120G>A | 3'UTR (SNP) | VAF 7/75 reads (9%) | called by muse, mutect2
- PCK2 | c.29+719A>C | Intron (SNP) | VAF 15/296 reads (5%) | called by muse, mutect2
- PTPRN2 | c.2344+7279T>A | Intron (SNP) | VAF 10/236 reads (4%) | called by muse, mutect2
